PECGS case C083-000044 — USC PE-CGS: Optimizing Engagement of Hispanic Colorectal Cancer Patients in Cancer Genomic Characterization Studies (PECGS-COPECC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Rectosigmoid junction.
https://portal.gdc.cancer.gov/cases/b343fdd5-7928-46f3-a370-5b9d5aec2075

Demographics
Sex at birth: female; Race: white; Ethnicity: hispanic or latino; Age at index: 45 years; Year of birth: 1977; Education level: Some High School or Less.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Age at diagnosis: 45.4 years (16,582 days); AJCC clinical stage: Stage IIB; AJCC pathologic stage: Stage IIB; Progression or recurrence: no.

Other clinical attributes
- BMI: 37.97; Menopause status: Postmenopausal.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Pack years smoked: 0; Alcohol history: Yes.

Biospecimens (2 samples)
- Sample C083-000044_Germline: Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample C083-000044_Tumor: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
